TARGET case TARGET-10-PASSUP — Acute Lymphoblastic Leukemia - Phase II (TARGET-ALL-P2)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Lymphoid Leukemias; Primary site: Hematopoietic and reticuloendothelial systems. Index date: not stated by GDC for this case (day counts are relative to an unstated reference).
https://portal.gdc.cancer.gov/cases/0acb6324-6e35-5a69-b7e4-f2d73eb43d6b

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Vital status: Dead; Days to death: 798 days (2.2 years).

Diagnoses (1)
1. Precursor B-cell lymphoblastic leukemia: ICD-O-3 morphology code: 9836/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Blood; Age at diagnosis: 7.8 years (2,856 days); Year of diagnosis: 2009; Days to last follow up: 798 days (2.2 years).

Biospecimens (1 sample)
- Sample TARGET-10-PASSUP-03A: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
